Somatic mutation profile of tumor specimen TCGA-49-4490-01A (aliquot TCGA-49-4490-01A-21D-1855-08) from TCGA case TCGA-49-4490, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 45.5 years (16,634 days).
Specimen TCGA-49-4490-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a41c93c6-e79d-4852-953a-c0597f74d0c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4490-11A (Solid Tissue Normal), aliquot TCGA-49-4490-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b57794b8-77dd-42a3-931b-5ca6e6ca3030

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 46/115 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACO2 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV53442061; called by muse, mutect2, varscan2
- ATRNL1 | c.3812G>T p.R1271L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); catalogued as COSV58080761; called by muse, varscan2
- CCDC93 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60120572; called by muse, mutect2
- CPS1 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51806103; called by muse, mutect2
- DNAH2 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV50013711; called by muse, mutect2, varscan2
- EFL1 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51604339; called by muse, mutect2, varscan2
- F2RL3 | c.114C>G p.S38R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.202); catalogued as COSV50185357; called by muse, mutect2
- HEY2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs1562712938, COSV64239613; called by muse, mutect2
- HLA-DRA | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100895079; called by muse, mutect2
- LINGO4 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV63214214; called by muse, mutect2
- MTF1 | c.1522T>C p.S508P | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV65988685; called by muse, mutect2
- NRDE2 | c.1564T>C p.F522L | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV62962644; called by muse, mutect2
- OR4Q3 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 28/595 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV59178011; called by muse, mutect2
- OR51Q1 | c.9G>C p.Q3H | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as COSV56178338; called by muse, mutect2, varscan2
- PARP3 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV51753636, COSV51757019; called by muse, mutect2
- PITPNM2 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54898473; called by muse, mutect2, varscan2
- PKD1L1 | c.8228G>C p.R2743T | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV51841795; called by muse, mutect2, varscan2
- PLXNA4 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201451359; called by muse, mutect2, varscan2
- PYROXD1 | c.1282C>G p.Q428E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV53708879; called by muse, mutect2, varscan2
- RDH8 | c.271G>C p.E91Q (on ENST00000651512; = p.E71Q on NM_015725.4) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.481); catalogued as COSV50674292; called by muse, mutect2
- RP1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs756961463, COSV55113657; called by muse, mutect2, varscan2
- RPS26 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100009180; called by muse, varscan2
- SAMD12 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV59047591; called by muse, mutect2, varscan2
- SYP | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1326473243, COSV99602954; called by muse, mutect2, varscan2
- TFCP2 | c.955C>G p.P319A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as COSV56932231; called by muse, mutect2
- UBR4 | c.6289G>A p.E2097K | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV64385642; called by muse, mutect2
- ZFP91 | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60158151; called by muse, mutect2, varscan2
- ZSCAN29 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV53018355; called by muse, mutect2, varscan2
- LONP1 | c.1652dup p.M552Hfs*3 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | called by mutect2, pindel
- AFG3L2 | c.456G>A p.L152= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV52313730; called by muse, mutect2, varscan2
- HSPA12A | c.351C>T p.A117= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs184358049; called by muse, mutect2, varscan2
- OR5D13 | c.474C>T p.S158= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as COSV62333247, COSV62335408; called by muse, mutect2
- PRDM9 | c.603T>C p.D201= | Silent (SNP) | VAF 18/295 reads (6%) | catalogued as rs1332524635, COSV57004453; called by muse, mutect2
- RNF31 | c.1965C>T p.S655= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV53758945; called by muse, mutect2, varscan2
- RTL10 | c.45C>T p.I15= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV100144235, COSV60735502; called by muse, mutect2, varscan2
- SGK3 | c.339C>T p.V113= | Silent (SNP) | VAF 12/210 reads (6%) | catalogued as COSV61894136; called by muse, mutect2
- TRIM39 | c.1122G>A p.R374= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs752509594, COSV100935800; called by muse, mutect2, varscan2
- UBQLN2 | c.1248T>C p.F416= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100592748; called by muse, mutect2, varscan2
- DCX | c.-22-535A>G | Intron (SNP) | VAF 74/179 reads (41%) | catalogued as rs150627878, COSV57567611; called by muse, mutect2, varscan2
